Somatic mutation profile of tumor specimen 0DXMNF from CCDI case PBCRNW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Spinal cord; Age at diagnosis: 10.5 years (3,831 days).
Specimen 0DXMNF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f080be64-dc32-487e-8855-83cbd4d2263b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DXMLO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd7b8942-aa84-4b12-ab02-a92d316149b6

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Nonsense Mutation 2, Intron 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPG | c.622C>T p.Q208* | Nonsense Mutation (SNP) | VAF 51/1194 reads (4%) | catalogued as rs754390834; called by muse, mutect2
- BORCS5 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 60/760 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53805690; called by muse, mutect2
- GCKR | c.1072C>T p.R358* | Nonsense Mutation (SNP) | VAF 49/1022 reads (5%) | catalogued as rs201754753; called by muse, mutect2
- RARA | c.826C>T p.R276W | Missense Mutation (SNP) | VAF 38/628 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786205678, COSV54190879; ClinVar: drug response; called by muse, mutect2
- TDRD9 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 35/696 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- C7orf61 | c.-56C>A | 5'UTR (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- GTF3C3 | c.102+25C>T | Intron (SNP) | VAF 67/252 reads (27%) | catalogued as rs781314192; called by muse, mutect2, varscan2
- WDR13 | c.42-60C>T | Intron (SNP) | VAF 5/47 reads (11%) | catalogued as COSV54331057; called by muse, mutect2
